CGCI case BLGSP-71-06-00019 — Burkitt Lymphoma Genome Sequencing Project (CGCI-BLGSP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/2721630e-8b64-4e64-8177-49f0fa84cfeb

Demographics
Sex at birth: female; Race: black or african american; Age at index: 11 years.

Diagnoses (1)
1. Burkitt lymphoma, NOS (Includes all variants): ICD-O-3 morphology code: 9687/3; Tissue or organ of origin: Hematopoietic system, NOS; Site of resection or biopsy: Bones of skull and face and associated joints; Classification of tumor: primary; Year of diagnosis: 2013; Method of diagnosis: Incisional Biopsy; Ann Arbor pathologic stage: Stage I; Ann Arbor B symptoms: Yes; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 310 days; Ann Arbor extranodal involvement: Yes; Burkitt lymphoma clinical variant: Endemic; Max tumor bulk site: Maxilla; Sites of involvement: Maxilla.
   Pathology details: Bone marrow malignant cells: No; Tumor largest dimension diameter: 12 cm.
   Treatment given: Treatment type: Chemotherapy; Initial disease status: Initial Diagnosis; Regimen or line of therapy: COM; Days to treatment start: 3 days; Days to treatment end: 79 days; Number of cycles: 6; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Methotrexate + Vincristine; Initial disease status: Initial Diagnosis; Days to treatment start: 3 days; Days to treatment end: 79 days; Number of cycles: 6; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; adjuvant Radiation Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 0 days; Karnofsky performance status: 50; ECOG performance status: 3.
- Days to follow up: 1 day; Disease response: With Tumor.
- Days to follow up: 310 days; Disease response: Tumor Free.

Molecular and laboratory tests
- BCL2 (IHC): Negative.
- BCL6 (IHC): Positive; Specialized molecular test: BCL6 > 30%.
- CD10 (IHC): Positive; Specialized molecular test: CD10 > 30%.
- CD20 (IHC): Positive.
- CD3 (IHC): Negative.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- MYC translocation (FISH): Abnormal, NOS.
- MYC translocation (FISH): Positive.
- Lactate Dehydrogenase 429 [Blood test normal range upper: 298].

Other clinical attributes
- Day 0: Weight: 38 kg.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample BLGSP-71-06-00019-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Maxilla; Preservation method: Frozen; Days to sample procurement: 0 days; Initial weight: 278 mg; Method of sample procurement: Incisional Biopsy; Tissue collection type: Prospective.
  Slide BLGSP-71-06-00019-01A-01-S2-HE: Section location: Bottom; Percent tumor cells: 80; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 20; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 10.
  Slide BLGSP-71-06-00019-01A-01-S1-HE: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 10; Percent neutrophil infiltration: 5.
- Sample BLGSP-71-06-00019-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Tissue collection type: Prospective.
  Slide BLGSP-71-06-00019-01B-01-S2-HE: Section location: Bottom; Percent tumor cells: 60; Percent tumor nuclei: 85; Percent normal cells: 10; Percent necrosis: 20; Percent stromal cells: 10; Percent lymphocyte infiltration: 40; Percent monocyte infiltration: 30; Percent neutrophil infiltration: 20.
  Slide BLGSP-71-06-00019-01B-01-S1-HE: Section location: Top; Percent tumor cells: 30; Percent tumor nuclei: 60; Percent normal cells: 40; Percent necrosis: 20; Percent stromal cells: 10; Percent lymphocyte infiltration: 50; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 20.
- Sample BLGSP-71-06-00019-01Z: Sample type: Tumor; Tissue type: Tumor.
  Slide BLGSP-71-06-00019-01-CD20-1-20X: Tissue microarray coordinates: B1,E2,C4.
  Slide BLGSP-71-06-00019-01-BCL2-1: Tissue microarray coordinates: B1,E2,C4.
  Slide BLGSP-71-06-00019-01-CD10: Tissue microarray coordinates: B1,E2,C4.
  Slide BLGSP-71-06-00019-01-Ki67: Tissue microarray coordinates: B1,E2,C4.
  Slide BLGSP-71-06-00019-01-Ki67-1-20X: Tissue microarray coordinates: B1,E2,C4.
  Slide BLGSP-71-06-00019-01-BCL2: Tissue microarray coordinates: B1,E2,C4.
  Slide BLGSP-71-06-00019-01-BCL6: Tissue microarray coordinates: B1,E2,C4.
  Slide BLGSP-71-06-00019-01-HE: Tissue microarray coordinates: B1,E2,C4.
  Slide BLGSP-71-06-00019-01-Ki67-1: Tissue microarray coordinates: B1,E2,C4.
  Slide BLGSP-71-06-00019-01-HE-1-20X: Tissue microarray coordinates: B1,E2,C4.
  Slide BLGSP-71-06-00019-01-CD10-1: Tissue microarray coordinates: B1,E2,C4.
  Slide BLGSP-71-06-00019-01-BCL2-1-20X: Tissue microarray coordinates: B1,E2,C4.
  Slide BLGSP-71-06-00019-01-CD20: Tissue microarray coordinates: B1,E2,C4.
  Slide BLGSP-71-06-00019-01-CD3-1-20X: Tissue microarray coordinates: B1,E2,C4.
  Slide BLGSP-71-06-00019-01-BCL6-1: Tissue microarray coordinates: B1,E2,C4.
  Slide BLGSP-71-06-00019-01-HE-1: Tissue microarray coordinates: B1,E2,C4.
  Slide BLGSP-71-06-00019-01-CD3-1: Tissue microarray coordinates: B1,E2,C4.
  Slide BLGSP-71-06-00019-01-CD10-1-20X: Tissue microarray coordinates: B1,E2,C4.
  Slide BLGSP-71-06-00019-01-CD20-1: Tissue microarray coordinates: B1,E2,C4.
  Slide BLGSP-71-06-00019-01-CD3: Tissue microarray coordinates: B1,E2,C4.
  Slide BLGSP-71-06-00019-01-BCL6-1-20X: Tissue microarray coordinates: B1,E2,C4.
- Sample BLGSP-71-06-00019-99A: Sample type: Granulocytes; Tissue type: Normal; Specimen type: Granulocytes; Preservation method: Frozen; Days to sample procurement: 1 day; Method of sample procurement: Blood Draw; Tissue collection type: Prospective.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; Days from index date to last known alive: 1; History neoadjuvant treatment: No; Tumor status: With tumor; Lost to follow-up: No; New tumor event diagnosis indicator: No.
- Primary pathology: Histologic diagnosis: Burkitt lymphoma (BL), classic morphology; Extranodal site involvement: 1; Lymph nodes examined: No.
- Primary pathology, Lymph node involvement sites: Lymph node involvement site: No Known Nodal Involvement.
- Stage record, Ann arbor: B symptoms present indicator: Yes.
- Tests performed: LDH level: 429; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 3: Immunophenotypic analysis tested: BCL2.
- Tests performed, Genetic testing results, Genetic testing result 4: Immunophenotypic analysis tested: CD20.
- Tests performed, Genetic testing results, Genetic testing result 6: Immunophenotypic analysis tested: CD3.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result: Genetic abnormality tested: C-myc.
- Follow-up form 1: Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response; New tumor event diagnosis indicator: No.
- Treatments, Treatment: Therapy regimen: Initial; Chemo end reporting period: Yes; Pharmaceutical regimen: Other Pharmaceutical Regimen (please specify); Pharma adjuvant cycles count: 6.
